Gene-level copy-number profile of tumor specimen ALCH-ADWO-TTP1-A from ALCHEMIST case ALCH-ADWO, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 66.6 years (24,338 days).
Specimen ALCH-ADWO-TTP1-A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 1bf48b8b-fa14-44ec-b0b1-2251aee0562d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-ADWO-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,713 have no estimate.
https://portal.gdc.cancer.gov/files/875d843e-404b-40da-9710-41e86e36f3e3

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 44; copy number 1: 15,655; copy number 2: 31,521; copy number 3: 9,834; copy number 4: 1,829; copy number 5: 11; copy number 6: 16.

Homozygous deletions (total copy number 0; autosomes only): 13 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:57,598–71,585, 2 genes: OR4G11P, OR4F5.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr15:43,637,632–43,643,023, 2 genes (within-gene range 0–2): RNU6-610P, AC011330.2.
- chr19:405,445–409,147, 1 gene: C2CD4C.
- chr19:1,228,287–1,259,140, 4 genes (within-gene range 0–1): CBARP, AC004221.1, ATP5F1D, MIDN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 27 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr9:61,581,813–61,642,494, 3 genes, copy number 5: AL935212.3, FAM242D, Y_RNA.
- chr11:90,017,611–90,087,131, 8 genes, copy number 5: AP004607.6, TRIM49C, AP004607.2, AP004607.4, TRIM64EP, AP004607.5, AP000827.1, UBTFL1.
- chr17:72,642,731–73,312,005, 16 genes, copy number 6: AC080037.2, SLC39A11, RN7SKP180, AC080037.1, AC011120.1, ATG12P1, POLR3KP2, AC097641.1, SSTR2, COG1, AC097641.2, FAM104A, C17orf80, AC087301.1, CPSF4L, CDC42EP4.

Autosomal genes at a single copy (total copy number 1): 12,853. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
